Somatic mutation profile of tumor specimen TCGA-L5-A4ON-01A (aliquot TCGA-L5-A4ON-01A-11D-A27G-09) from TCGA case TCGA-L5-A4ON, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 65.6 years (23,970 days).
Specimen TCGA-L5-A4ON-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9fba625-6188-4dec-8859-4f330b347f60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4ON-11A (Solid Tissue Normal), aliquot TCGA-L5-A4ON-11A-21D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30f0d1c9-7d04-474b-9184-194d6072fef4

The open-access MAF lists 170 somatic variants for this specimen: 128 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 37, Nonsense Mutation 6, Intron 2, Frame Shift Ins 2, Splice Site 2, RNA 2, In Frame Ins 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SERPINA1 | c.1158dup p.E387Rfs*14 | Frame Shift Ins (INS) | VAF 18/34 reads (53%) | catalogued as rs764325655; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SLC25A4 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs886041081, COSV55669674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPAST | c.1276C>G p.L426V | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1060502227, CD052507, CM000436, CM101456, COSV59514516; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 202/280 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.2602A>T p.R868* | Nonsense Mutation (SNP) | VAF 26/41 reads (63%) | catalogued as COSV50736480; called by muse, mutect2, varscan2
- ALK | c.2722C>A p.Q908K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.101); catalogued as rs1468545699; called by muse, mutect2, varscan2
- ANK1 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs563833117, COSV55884212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP3B1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.65); catalogued as rs140209190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP5B1 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as rs780751916, COSV100375997; called by muse, mutect2, varscan2
- ASXL1 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60103095, COSV60109115; called by muse, mutect2, varscan2
- ATP2B2 | c.1996C>T p.R666C (on ENST00000352432; = p.R632C on NM_001683.5) | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100660646; called by muse, mutect2, varscan2
- ATP8A1 | c.2006A>C p.E669A | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52527731; called by muse, mutect2, varscan2
- BICC1 | c.1333T>G p.L445V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV54062819; called by muse, mutect2, varscan2
- C4orf50 | c.431A>C p.K144T (on ENST00000324058; = p.K1376T on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as rs1472941743; called by muse, mutect2, varscan2
- C6orf118 | c.356T>G p.V119G | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1053621216; called by muse, mutect2, varscan2
- CCIN | c.1125dup p.T376Dfs*22 | Frame Shift Ins (INS) | VAF 14/72 reads (19%) | catalogued as rs753843450; called by mutect2, pindel, varscan2
- CDHR3 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs200623269; called by muse, mutect2, varscan2
- CHRNB2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63808092; called by muse, mutect2, varscan2
- CPXM2 | c.1391G>T p.W464L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53869746; called by muse, mutect2, varscan2
- CSMD1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201992115, COSV68170651; called by muse, mutect2, varscan2
- DAB2IP | c.1213G>A p.G405R (on ENST00000408936; = p.G377R on NM_032552.3) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.57); PolyPhen probably damaging (1); catalogued as rs142519289; called by muse, mutect2, varscan2
- DCSTAMP | c.731A>C p.N244T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99887139; called by muse, mutect2, varscan2
- DLC1 | c.546A>C p.K182N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV52291120; called by muse, mutect2, varscan2
- EPHA7 | c.2435A>C p.K812T | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as rs940477878; called by muse, mutect2, varscan2
- ETAA1 | c.722A>G p.H241R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.131); catalogued as rs757890788; called by muse, mutect2, varscan2
- FBXL7 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs750820412, COSV61643759; called by muse, mutect2, varscan2
- FCRL1 | c.880T>C p.F294L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1183041228; called by muse, mutect2, varscan2
- GRID1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769943428; called by muse, mutect2, varscan2
- HIPK2 | c.3436G>A p.V1146M | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs544605371; called by muse, mutect2, varscan2
- HRNR | c.3100T>A p.S1034T | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.487); catalogued as rs763111095; called by muse, mutect2, varscan2
- HTR1A | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100109193; called by muse, mutect2, varscan2
- IMPG2 | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99516457; called by muse, mutect2, varscan2
- ITGA8 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs147309422; called by muse, varscan2
- KCNK3 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1296989441, COSV57192427; called by muse, mutect2, varscan2
- KCNT2 | c.2897T>G p.L966R | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.418); catalogued as COSV54069295, COSV54070653, COSV54077408; called by muse, mutect2, varscan2
- LAMA1 | c.349T>C p.F117L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766888109, COSV101057499; called by muse, mutect2, varscan2
- LAMA5 | c.10255C>T p.R3419C | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs771570265; called by muse, varscan2
- LOXL2 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as rs773669008; called by muse, mutect2, varscan2
- LRP4 | c.1825G>A p.G609R | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.498); catalogued as rs1389594811; called by muse, mutect2, varscan2
- MRGPRF | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs758512888, COSV100307946; called by muse, mutect2, varscan2
- MUC16 | c.17315T>G p.I5772S | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV101199978; called by muse, mutect2, varscan2
- NBEAL2 | c.5692G>A p.E1898K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs1182492163; called by muse, mutect2, varscan2
- NCAM2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs765814157, COSV53055753; called by muse, mutect2, varscan2
- NLGN1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 35/78 reads (45%) | catalogued as COSV100848839; called by muse, mutect2, varscan2
- NOTCH2 | c.5152C>T p.R1718C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1233590749, COSV56691983; called by muse, mutect2, varscan2
- NRSN2 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.369); catalogued as rs1161618541; called by muse, mutect2, varscan2
- NSUN7 | c.1088G>A p.R363K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as rs772583401, COSV57275949; called by muse, mutect2, varscan2
- OLFML2B | c.2005C>T p.R669W | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368291911; called by muse, mutect2, varscan2
- OLIG3 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs750507091; called by muse, mutect2, varscan2
- OR10H4 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs140667599; called by muse, mutect2, varscan2
- OR13C2 | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.516); catalogued as COSV101604864, COSV73377743; called by muse, mutect2, varscan2
- OR2D3 | c.80A>C p.K27T | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1455135482; called by muse, varscan2
- OR2L2 | c.784A>G p.R262G | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1459885993; called by muse, mutect2, varscan2
- OR52E2 | c.286T>G p.F96V | Missense Mutation (SNP) | VAF 42/53 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV58612584; called by muse, mutect2, varscan2
- OR52J3 | c.827T>G p.L276R | Missense Mutation (SNP) | VAF 51/66 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66747737; called by muse, mutect2, varscan2
- PALD1 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs141972259; called by muse, mutect2
- POU4F2 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750317758; called by muse, mutect2, varscan2
- PSD2 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758502460, COSV51202986; called by muse, mutect2, varscan2
- PSG3 | c.593A>C p.N198T | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs16976174; called by muse, mutect2, varscan2
- REXO1 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs375966236; called by muse, mutect2, varscan2
- SEPTIN11 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated (0.83); PolyPhen benign (0.023); catalogued as rs368053703; called by muse, mutect2, varscan2
- SI | c.4349T>G p.V1450G | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100015334; called by muse, mutect2, varscan2
- SLC30A9 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100047969; called by muse, mutect2, varscan2
- SPHK2 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs776451771; called by muse, mutect2, varscan2
- SPTA1 | c.1922A>G p.Q641R | Missense Mutation (SNP) | VAF 82/162 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100935553, COSV63751996; called by muse, mutect2, varscan2
- SPTA1 | c.226T>G p.L76V | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63748768, COSV63754867; called by muse, mutect2, varscan2
- TIGD7 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as rs767003342, COSV51915849; called by muse, mutect2, varscan2
- TMEM67 | c.2692G>C p.D898H | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767109906; called by muse, mutect2, varscan2
- TOGARAM2 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768497249; called by muse, mutect2, varscan2
- URB2 | c.2828C>T p.T943M | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs749450816, COSV50981294; called by muse, mutect2, varscan2
- WDR17 | c.3431G>T p.R1144L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as COSV54568336; called by muse, mutect2, varscan2
- ZNF43 | c.2174A>C p.K725T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV61686480; called by muse, mutect2, varscan2
- ABCA12 | c.494T>G p.L165R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- AGBL1 | c.1103T>G p.L368R | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.36); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ARFGEF3 | c.1028T>C p.L343P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ASS1 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CCDC60 | c.166A>C p.S56R | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- CELF2 | c.1301T>G p.F434C (on ENST00000416382 / NM_001025077.3; = p.F447C on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CHMP1B | c.586C>G p.R196G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CHRFAM7A | c.33+2T>C p.X11_splice | Splice Site (SNP) | VAF 8/60 reads (13%) | called by mutect2, varscan2
- CNTNAP5 | c.171A>C p.Q57H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- COL27A1 | c.4755+1G>A p.X1585_splice | Splice Site (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- COL6A5 | c.6052A>C p.S2018R (on ENST00000312481; = p.S2014R on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL6A6 | c.6102T>G p.N2034K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CYSLTR1 | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCAF12L2 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2
- DTX2 | c.791_793dup p.T264dup | In Frame Ins (INS) | VAF 18/32 reads (56%) | called by mutect2, varscan2
- EYS | c.1691T>C p.L564P | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- FANCA | c.3578T>G p.L1193R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FMO4 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- GUCY2C | c.436A>C p.S146R | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFI16 | c.1880A>C p.K627T (on ENST00000295809 / NM_001364867.2; = p.K571T on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- KRR1 | c.1019A>T p.K340I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KRTAP6-1 | c.124T>C p.F42L | Missense Mutation (SNP) | VAF 44/103 reads (43%) | PolyPhen benign (0.036); called by muse, mutect2, varscan2
- LPAR1 | c.1057T>G p.L353V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- LZTS1 | c.1628A>G p.Q543R | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- MED12L | c.4256C>T p.A1419V | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2
- MMP10 | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MMP16 | c.1283T>A p.I428K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP28 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- NDST4 | c.506A>G p.E169G | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- OR4K13 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52E4 | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OR5H6 | c.389T>C p.L130P (on ENST00000642105; = p.L114P on NM_001005479.2) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PCDH17 | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH17 | c.2560A>C p.I854L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA4 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 80/111 reads (72%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCNX3 | c.3829G>C p.V1277L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- PLCH2 | c.2714G>A p.G905D | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2
- PRAMEF15 | c.1010A>C p.N337T | Missense Mutation (SNP) | VAF 115/238 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- PRAMEF8 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKDC | c.8670C>G p.I2890M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- PSG7 | c.791del p.P264Lfs*12 | Frame Shift Del (DEL) | VAF 181/303 reads (60%) | called by mutect2, pindel, varscan2
- SACS | c.8363T>G p.V2788G | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- SCN1A | c.3737A>C p.K1246T (on ENST00000303395 / NM_001202435.3; = p.K1235T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SEC16B | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SEL1L2 | c.1084T>G p.F362V | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- SORBS2 | c.3050C>T p.S1017F (on ENST00000284776 / NM_021069.5; = p.S583F on NM_003603.6) | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPATA31A3 | c.3374T>A p.L1125H | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- STX6 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2
- TBCEL | c.24T>G p.S8R | Missense Mutation (SNP) | VAF 46/56 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- TLL1 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- TRIM71 | c.1223T>C p.L408P | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRPM6 | c.4818C>G p.D1606E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- WDR12 | c.1250C>T p.T417I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZBBX | c.900A>T p.K300N | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- ZFP14 | c.1507A>G p.T503A | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ZNF829 | c.663T>A p.F221L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAMTS9 | c.2862T>G p.G954= | Silent (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2, varscan2
- ARID1B | c.4917G>C p.T1639= | Silent (SNP) | VAF 41/183 reads (22%) | called by muse, mutect2, varscan2
- DNAH11 | c.7878G>A p.P2626= | Silent (SNP) | VAF 54/108 reads (50%) | catalogued as rs748463983, COSV60938783, COSV60951974; called by muse, mutect2, varscan2
- EBF2 | c.357C>T p.V119= | Silent (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- EPB41L3 | c.3183A>G p.K1061= | Silent (SNP) | VAF 60/94 reads (64%) | called by muse, mutect2, varscan2
- FCRL2 | c.888A>G p.P296= | Silent (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- FNDC1 | c.945C>T p.I315= | Silent (SNP) | VAF 72/105 reads (69%) | catalogued as COSV51933362; called by muse, mutect2, varscan2
- GABBR1 | c.1446C>T p.N482= | Silent (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- GBA2 | c.2400T>C p.A800= | Silent (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- GNL2 | c.864G>A p.P288= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs772092924; called by muse, mutect2, varscan2
- GPBAR1 | c.927C>T p.D309= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- HYDIN | c.711T>G p.T237= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV55485543; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.135A>G p.G45= | Silent (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2
- JCAD | c.2523G>A p.E841= | Silent (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- LRP1B | c.6372C>T p.T2124= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs779012955, COSV101255700, COSV101262314, COSV67237422; called by muse, mutect2
- MLIP | c.1284T>G p.S428= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs1465492458; called by muse, mutect2, varscan2
- NAA15 | c.1989G>A p.P663= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs931332031; called by muse, mutect2, varscan2
- NAV1 | c.513G>T p.P171= | Silent (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- NEURL4 | c.3030C>A p.S1010= | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- ORM1 | c.399C>T p.D133= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs111906642; called by muse, mutect2, varscan2
- PCDHA12 | c.2067C>T p.P689= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs1562735979, COSV56513868; called by muse, mutect2, varscan2
- PLOD3 | c.1173G>A p.L391= | Silent (SNP) | VAF 21/30 reads (70%) | called by muse, mutect2, varscan2
- PLXND1 | c.3780C>T p.I1260= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs975388195; called by muse, mutect2, varscan2
- PRSS36 | c.756C>T p.G252= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs775399871, COSV99191213; called by muse, mutect2, varscan2
- QKI | c.795C>T p.N265= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs769837755, COSV51694187; called by muse, mutect2, varscan2
- RALYL | c.516C>A p.V172= | Silent (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- RIPOR3 | c.459C>T p.R153= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs374374141; called by muse, mutect2
- SDK1 | c.2316G>A p.P772= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs375976550; called by muse, mutect2, varscan2
- STAG1 | c.783G>A p.K261= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as COSV52610363, COSV99367197; called by muse, mutect2, varscan2
- TGM6 | c.135C>T p.S45= | Silent (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- TIAM1 | c.2928C>T p.T976= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs557120271, COSV54548964; called by muse, mutect2, varscan2
- TPSD1 | c.198C>T p.C66= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs377281598, COSV52976180; called by mutect2, varscan2
- TRIM42 | c.1242T>C p.Y414= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- TXNRD2 | c.576G>A p.P192= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs1208571214; called by muse, mutect2, varscan2
- ZNF496 | c.1179C>T p.T393= | Silent (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- ZNF680 | c.1269A>G p.R423= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- ZNF831 | c.84T>C p.G28= | Silent (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2
- FOLH1B | n.1475T>G | RNA (SNP) | VAF 20/34 reads (59%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.59T>C | RNA (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31294A>G | Intron (SNP) | VAF 64/151 reads (42%) | catalogued as COSV99829872; called by muse, mutect2, varscan2
- NTM | c.*2G>A | 3'UTR (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100867808; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1936T>G | Intron (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100678577; called by muse, mutect2, varscan2
